Somatic mutation profile of tumor specimen 0DTC64 from CCDI case PBCJLZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 13.2 years (4,830 days).
Specimen 0DTC64: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43fc3138-3c80-4fbe-85b5-3f8b2788daa0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTC5W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37cbf254-a07a-4ccc-a253-18ac46ec8735

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IQCB1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 174/401 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100181730; called by muse, mutect2, varscan2
- TBX3 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 24/425 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV57473613, COSV57476383; called by muse, mutect2
- HNRNPA2B1 | c.444G>T p.Q148H (on ENST00000354667 / NM_031243.3; = p.Q136H on NM_002137.4) | Missense Mutation (SNP) | VAF 123/399 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- MEX3D | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 71/224 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- MOCOS | c.1670T>C p.V557A | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC25A40 | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 95/285 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- FBLN5 | c.1332G>A p.S444= | Silent (SNP) | VAF 24/554 reads (4%) | catalogued as rs959066731; called by muse, mutect2
- HDAC8 | c.321G>C p.G107= | Silent (SNP) | VAF 43/342 reads (13%) | called by mutect2, varscan2
- LOXHD1 | c.5349C>T p.Y1783= (on ENST00000642948; = p.Y1721= on NM_144612.7) | Silent (SNP) | VAF 140/330 reads (42%) | catalogued as rs201819544, COSV100190213, COSV99039139; called by muse, mutect2, varscan2
- HDAC8 | c.-41C>G | 5'UTR (SNP) | VAF 94/222 reads (42%) | called by muse, mutect2, varscan2
- PAX5 | c.*15C>T | 3'UTR (SNP) | VAF 42/366 reads (11%) | catalogued as rs587777963; ClinVar: not provided; called by muse, mutect2, varscan2
